Gene-level copy-number profile of tumor specimen TCGA-86-8055-01A from TCGA case TCGA-86-8055, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.7 years (29,124 days).
Specimen TCGA-86-8055-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.496c0fd9-d622-42d5-bea3-5f9aace7f901.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8055-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dcd4ce99-40c2-43cf-b420-5c3eecd8c4e5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 3,890; copy number 2: 17,693; copy number 3: 21,323; copy number 4: 14,485; copy number 5: 1,007; copy number 6: 267; copy number 7: 357; copy number 8: 437; copy number 9: 47; copy number 10: 22; copy number 12: 78; copy number 13: 103; copy number 14: 3; copy number 16: 2; copy number 18: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8055-01A-11D-2237-01): tumor purity 0.28, ploidy 3.5, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,929,457–22,128,103, 9 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,143 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:144,170,873–146,407,359, 28 genes, copy number 7 (within-gene range 5–7): KCTD16, AC008652.1, AC109441.1, CKS1BP5, AC008716.1, RN7SKP246, AC132803.1, NAMPTP2, ASS1P10, AC137770.1, AC008700.1, PRELID2, AC011411.1, GRXCR2, SH3RF2, AC005351.1, PLAC8L1, AC091887.1, LARS1, RPL35AP16, RPL35AP17, AC091959.1, RBM27, RNU7-180P, AC011396.2, POU4F3, AC011396.3, AC011396.1.
- chr5:148,312,419–149,276,776, 17 genes, copy number 7 (within-gene range 5–7): SPINK7, SPINK9, AC091948.1, FBXO38, Metazoa_SRP, AC114939.1, HTR4, AC008627.1, ADRB2, SH3TC2, AC116312.1, RNU6-732P, MIR584, SH3TC2-DT, RN7SKP145, ABLIM3, AC012613.1.
- chr5:162,424,042–165,241,756, 23 genes, copy number 10–16: AC113414.1, RNU6-164P, ARL2BPP5, MRPL57P6, AC008723.1, CCNG1, NUDCD2, HMMR, HMMR-AS1, MAT2B, AC010291.1, AC116917.1, RNU6-168P, AC008432.1, LSM1P2, AC008662.1, AC008662.2, AC109466.1, LINC02143, AC008446.1, RNU6-209P, AC091973.1, LINC01938.
- chr5:171,724,575–174,330,503, 63 genes, copy number 7 (broad region; genes not listed).
- chr7:70,972–34,299,012, 600 genes, copy number 7–13 (broad region; genes not listed).
- chr7:40,775,558–62,275,678, 353 genes, copy number 7–18 (broad region; genes not listed).
- chr14:43,274,824–43,596,683, 6 genes, copy number 7: TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P.
- chr18:8,133,203–8,414,304, 6 genes, copy number 7: AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1.
- chr18:20,946,906–23,026,488, 47 genes, copy number 9 (within-gene range 5–9): ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2.

Autosomal genes at a single copy (total copy number 1): 3,002. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
